Somatic mutation profile of tumor specimen TCGA-67-3774-01A (aliquot TCGA-67-3774-01A-01D-1040-01) from TCGA case TCGA-67-3774, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.1 years (26,704 days).
Specimen TCGA-67-3774-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b56ddb2-067c-4f81-8ca4-c423dc8b6738.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-67-3774-10A (Blood Derived Normal), aliquot TCGA-67-3774-10A-01D-1489-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d1d4767-656d-4a42-b402-e61f902de293

The open-access MAF lists 121 somatic variants for this specimen: 84 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 33, Nonsense Mutation 5, Frame Shift Del 3, RNA 2, Splice Region 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA8 | c.3518T>C p.F1173S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52202679; called by muse, mutect2
- ACTRT1 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV64418931, COSV64419524; called by muse, mutect2, varscan2
- ADCY8 | c.3548C>T p.P1183L | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV53910375; called by muse, mutect2, varscan2
- ADGRV1 | c.1927G>A p.V643I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.2); catalogued as COSV67986493; called by muse, mutect2
- AHNAK | c.8486A>T p.H2829L | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV57215609; called by muse, varscan2
- APOBEC3G | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV68470349; called by muse, mutect2, varscan2
- BCL2 | c.10G>C p.A4P | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV61371817, COSV61381654; called by muse, mutect2, varscan2
- BTNL9 | c.1047C>A p.S349R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV59796810; called by muse, mutect2, varscan2
- CACNA1D | c.4445T>C p.L1482S (on ENST00000350061 / NM_001128840.3; = p.L1502S on NM_000720.4) | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55449140; called by muse, mutect2, varscan2
- CACNA2D3 | c.1948G>T p.A650S | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.35); catalogued as COSV55544330; called by muse, mutect2, varscan2
- CAPN5 | c.694G>A p.G232S (on ENST00000456580; = p.G192S on NM_004055.5) | Missense Mutation (SNP) | VAF 182/746 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53688330; called by muse, mutect2, varscan2
- CAPN5 | c.892G>A p.D298N (on ENST00000456580; = p.D258N on NM_004055.5) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.857); catalogued as COSV53688342; called by muse, mutect2, varscan2
- CAPN5 | c.992G>A p.W331* (on ENST00000456580; = p.W291* on NM_004055.5) | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV53688350; called by muse, varscan2
- CAPN5 | c.1233G>C p.Q411H (on ENST00000456580; = p.Q371H on NM_004055.5) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV53688372; called by muse, mutect2
- CAPN5 | c.1318G>A p.E440K (on ENST00000456580; = p.E400K on NM_004055.5) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.309); catalogued as COSV53688381; called by muse, mutect2, varscan2
- CASR | c.2077C>A p.L693I (on ENST00000490131; = p.L770I on NM_000388.4) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.146); catalogued as COSV56138101; called by muse, mutect2, varscan2
- CCDC27 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV53900680; called by muse, mutect2, varscan2
- CEP85 | c.2102A>G p.N701S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775213951, COSV53329801; called by muse, mutect2, varscan2
- CHST1 | c.567C>A p.N189K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57323868; called by muse, mutect2, varscan2
- DAW1 | c.42A>T p.G14= | Splice Region (SNP) | VAF 13/53 reads (25%) | catalogued as COSV59365900; called by muse, mutect2, varscan2
- DCAF4L2 | c.414G>T p.L138F | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.862); catalogued as COSV60479278; called by muse, mutect2, varscan2
- EFHB | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55547798, COSV55548892; called by muse, mutect2, varscan2
- ELMO1 | c.932C>A p.T311N | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV60306491; called by muse, mutect2, varscan2
- ENTPD4 | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV62269200; called by muse, mutect2, varscan2
- ERMAP | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771020983, COSV60273608; called by muse, mutect2, varscan2
- EXOG | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55063514; called by muse, mutect2, varscan2
- F8 | c.4856C>A p.S1619Y | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV64274144; called by muse, mutect2, varscan2
- FAM83B | c.1622G>T p.R541L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775965658, COSV60922593; called by muse, mutect2, varscan2
- FAM83G | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373051640; called by muse, mutect2, varscan2
- GAD2 | c.1225G>C p.V409L | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV52158703; called by muse, mutect2, varscan2
- GALT | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs1448701207, COSV66593007; called by muse, mutect2
- GRB2 | c.158T>G p.I53R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57304985; called by muse, mutect2, varscan2
- HOXB1 | c.122G>T p.S41I | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV99495359; called by muse, varscan2
- HOXB1 | c.121A>T p.S41C | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99495363; called by muse, varscan2
- IFT81 | c.489A>G p.I163M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs774415653, COSV54363028; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV56266184; called by muse, mutect2, varscan2
- ITIH6 | c.2359G>T p.G787C | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); catalogued as COSV54489750; called by muse, mutect2, varscan2
- KIAA0232 | c.3140C>G p.P1047R | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.221); catalogued as rs1168252443, COSV56925774; called by muse, mutect2, varscan2
- KLK3 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 68/305 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.839); catalogued as rs773127519, COSV58100763; called by muse, mutect2, varscan2
- LAMA5 | c.6298C>T p.R2100C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs752677069, COSV53361267; called by muse, mutect2
- LILRB1 | c.721C>A p.P241T (on ENST00000427581; = p.P205T on NM_006669.6) | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV61116765, COSV61118652; called by muse, varscan2
- LRRC32 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs753547615, COSV52633282; called by muse, mutect2, varscan2
- MAP3K11 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58419909; called by muse, mutect2, varscan2
- ME1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV63839643; called by muse, varscan2
- MED13L | c.4547C>G p.T1516S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.437); catalogued as rs1298577093, COSV56121168; called by muse, mutect2, varscan2
- MME | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV64706889, COSV64707797; called by muse, mutect2
- NALCN | c.4843G>A p.E1615K | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.288); catalogued as rs756729162, COSV51939252; called by muse, mutect2, varscan2
- NOTCH1 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs779375653, COSV53056338; called by muse, mutect2, varscan2
- NPFFR2 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58150337, COSV58155063; called by muse, mutect2, varscan2
- OR10J1 | c.902G>A p.C301Y | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV71128850, COSV71128932; called by muse, mutect2, varscan2
- OR2T34 | c.99C>A p.Y33* | Nonsense Mutation (SNP) | VAF 25/156 reads (16%) | catalogued as COSV100170286; called by muse, mutect2, varscan2
- PARP1 | c.3023A>G p.N1008S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1219278582, COSV64690731; called by muse, mutect2, varscan2
- PCDH8 | c.2911G>T p.G971W | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV100131111, COSV58812848; called by muse, mutect2, varscan2
- PCSK7 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58007547; called by muse, varscan2
- PDE1C | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58515518, COSV58520064; called by muse, mutect2, varscan2
- PDS5A | c.2601G>A p.M867I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as COSV57826514; called by muse, mutect2, varscan2
- POF1B | c.1220_1223del p.S407Ffs*12 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs1444043025; called by mutect2, pindel, varscan2
- PPM1K | c.999C>G p.Y333* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV55796092, COSV55796100; called by muse, mutect2, varscan2
- PRAMEF1 | c.892T>A p.L298M | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100179309, COSV60010135; called by muse, mutect2, varscan2
- PZP | c.4321C>A p.Q1441K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54361964; called by muse, mutect2, varscan2
- RASL11B | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 121/602 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV50535222; called by muse, mutect2, varscan2
- RELB | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); catalogued as COSV55510814; called by muse, mutect2, varscan2
- ROBO2 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59914086, COSV59919821; called by muse, mutect2, varscan2
- RYR2 | c.7993G>C p.A2665P | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100771999, COSV63672383, COSV63688685; called by muse, mutect2
- SIRPG | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53807804; called by muse, mutect2, varscan2
- SLC36A4 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV58396351; called by muse, mutect2, varscan2
- STBD1 | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52953926; called by muse, mutect2, varscan2
- SULT4A1 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as COSV50781268; called by muse, mutect2, varscan2
- TBX18 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV63737042; called by muse, mutect2, varscan2
- TLK2 | c.776A>T p.Y259F | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV58300852; called by muse, mutect2, varscan2
- TM7SF2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.515); catalogued as COSV54207701; called by muse, varscan2
- TNFSF13B | c.205G>C p.V69L | Missense Mutation (SNP) | VAF 83/309 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1303186225, COSV65516367; called by muse, mutect2, varscan2
- TNN | c.3303C>G p.D1101E | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53427344; called by muse, mutect2, varscan2
- TRAK1 | c.1604G>T p.S535I (on ENST00000327628 / NM_001349247.2; = p.S477I on NM_014965.5) | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58259417; called by muse, mutect2, varscan2
- TRIM58 | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV63572902; called by muse, mutect2, varscan2
- UGT2B7 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as COSV59443736; called by muse, mutect2, varscan2
- UNC93A | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 63/318 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs1487332415, COSV57808816; called by muse, mutect2, varscan2
- ZNF536 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765701898, COSV62825384, COSV62833806; called by muse, mutect2
- ZNF536 | c.2485G>T p.A829S | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV62819610; called by muse, mutect2, varscan2
- ZNF835 | c.950A>G p.Q317R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.423); catalogued as rs749435198, COSV73379197; called by muse, mutect2, varscan2
- MTTP | c.2228del p.L743Yfs*5 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, varscan2
- TKT | c.945del p.I315Mfs*56 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | called by mutect2, pindel, varscan2
- ACIN1 | c.2268G>C p.L756= | Silent (SNP) | VAF 60/211 reads (28%) | catalogued as COSV52976978; called by muse, mutect2, varscan2
- ALDH1L1 | c.231G>T p.G77= | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as COSV56414737; called by muse, mutect2, varscan2
- ANK1 | c.2643T>A p.S881= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV55883225; called by muse, mutect2, varscan2
- ASXL3 | c.3624T>A p.P1208= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV52467698; called by muse, mutect2, varscan2
- ATAD2B | c.3366G>T p.V1122= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99477159; called by muse, mutect2
- CHD6 | c.4161C>A p.P1387= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV64691296; called by muse, mutect2, varscan2
- COL17A1 | c.345C>T p.G115= | Silent (SNP) | VAF 42/235 reads (18%) | catalogued as COSV62227116; called by muse, mutect2, varscan2
- COL4A1 | c.3234T>A p.P1078= | Silent (SNP) | VAF 118/504 reads (23%) | catalogued as COSV65426756; called by muse, mutect2, varscan2
- COL4A6 | c.3825C>A p.P1275= | Silent (SNP) | VAF 23/152 reads (15%) | catalogued as COSV57868081; called by muse, varscan2
- CSMD1 | c.6390T>C p.H2130= (on ENST00000520002; = p.H2129= on NM_033225.6) | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV59331849; called by muse, mutect2, varscan2
- DSG1 | c.252A>T p.T84= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV57136075; called by muse, mutect2, varscan2
- FASN | c.7428C>T p.V2476= | Silent (SNP) | VAF 41/215 reads (19%) | catalogued as COSV60755716; called by muse, mutect2, varscan2
- HNRNPL | c.1203T>C p.N401= | Silent (SNP) | VAF 53/238 reads (22%) | catalogued as rs1413890278, COSV55493005; called by muse, mutect2, varscan2
- IGSF9B | c.3888C>T p.D1296= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV58068333; called by muse, varscan2
- KRTAP10-9 | c.570T>A p.P190= | Silent (SNP) | VAF 198/963 reads (21%) | catalogued as COSV59964791; called by muse, mutect2, varscan2
- MOXD1 | c.1341G>A p.T447= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs202102392, COSV60945003; called by mutect2, varscan2
- NGEF | c.228G>A p.K76= | Silent (SNP) | VAF 88/495 reads (18%) | catalogued as rs577781370, COSV50925465, COSV50939069; called by muse, mutect2, varscan2
- OR4K1 | c.675C>A p.V225= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV53460452, COSV53461936; called by muse, mutect2, varscan2
- OR5D14 | c.870G>T p.L290= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV59456604, COSV59458899; called by muse, mutect2, varscan2
- ORC2 | c.282T>G p.V94= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV52239217; called by muse, mutect2, varscan2
- PCDH19 | c.393A>T p.A131= | Silent (SNP) | VAF 82/453 reads (18%) | catalogued as COSV55264270; called by muse, mutect2, varscan2
- PCDHA13 | c.108C>T p.P36= | Silent (SNP) | VAF 106/458 reads (23%) | catalogued as COSV56507728; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.906C>T p.P302= | Silent (SNP) | VAF 48/176 reads (27%) | catalogued as COSV59012576, COSV59014069; called by muse, mutect2, varscan2
- PER2 | c.105C>T p.S35= | Silent (SNP) | VAF 36/188 reads (19%) | catalogued as COSV54524227; called by muse, mutect2, varscan2
- RASGRF2 | c.1497A>C p.T499= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs753350732, COSV54130983; called by muse, mutect2, varscan2
- SCAI | c.156A>T p.P52= (on ENST00000336505 / NM_001144877.3; = p.P75= on NM_173690.5) | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV60613323; called by muse, mutect2, varscan2
- SHC2 | c.1146G>T p.L382= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV99198935; called by muse, mutect2
- SLC26A8 | c.2220C>A p.V740= | Silent (SNP) | VAF 49/290 reads (17%) | catalogued as COSV62886061, COSV62886866; called by muse, varscan2
- SPG11 | c.3711C>G p.A1237= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV55995804; called by muse, mutect2, varscan2
- UHRF1BP1 | c.504C>T p.R168= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV51956103; called by muse, mutect2, varscan2
- VPS51 | c.2322G>A p.V774= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs996078943, COSV54207678; called by muse, mutect2, varscan2
- ZNF43 | c.1557T>C p.F519= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV61684213; called by muse, mutect2, varscan2
- ZNF829 | c.324G>T p.L108= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV66986482; called by muse, mutect2, varscan2
- AC073310.1 | n.368C>A | RNA (SNP) | VAF 38/147 reads (26%) | called by muse, mutect2, varscan2
- AC073310.1 | n.369C>A | RNA (SNP) | VAF 39/147 reads (27%) | called by muse, mutect2, varscan2
- CSMD3 | c.178+59941T>A | Intron (SNP) | VAF 39/163 reads (24%) | catalogued as COSV99828009; called by muse, mutect2, varscan2
- PRND | chr20:4732516 A>T | 3'Flank (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
